Gene-level copy-number profile of tumor specimen ALCH-B1HF-TTP1-A from ALCHEMIST case ALCH-B1HF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 74.8 years (27,320 days).
Specimen ALCH-B1HF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 573dee41-c6b0-45ae-90d5-747e24d41d14.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1HF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,394 have no estimate.
https://portal.gdc.cancer.gov/files/b4759080-bf2e-42ae-9f7b-fb00446a0d67

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 58; copy number 1: 168; copy number 2: 19,929; copy number 3: 25,028; copy number 4: 9,539; copy number 5: 2,327; copy number 6: 400; copy number 7: 95; copy number 8: 17; copy number 9: 45; copy number 10: 32; copy number 11: 14; copy number 12: 84; copy number 13: 140; copy number 14: 10; copy number 15: 32; copy number 16: 90; copy number 18: 18; copy number 19: 2; copy number 21: 32; copy number 23: 14; copy number 24: 2; copy number 25: 4; copy number 26: 25; copy number 30: 18; copy number 33: 68; copy number 34: 7; copy number 37: 8; copy number 102: 4; copy number 105: 11; copy number 134: 5; copy number 181: 3.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,571,585–31,577,898, 1 gene (within-gene range 0–3): AC114488.1.
- chr4:49,486,926–49,523,857, 4 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr5:191,495–196,341, 2 genes: LRRC14B, AC021087.4.
- chr9:68,302,867–68,330,626, 3 genes (within-gene range 0–3): FOXD4L3, AL353608.3, AL353608.1.
- chr15:25,169,337–25,241,827, 40 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39.
- chr22:30,239,194–30,289,622, 6 genes (within-gene range 0–2): LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 780 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:271,670–438,291, 1 gene, copy number 8 (within-gene range 2–8): PDCD6-AHRR.
- chr5:321,759–438,291, 2 genes, copy number 8 (within-gene range 2–8): AHRR, AC010442.1.
- chr5:1,544,107–1,551,710, 1 gene, copy number 7: AC091849.2.
- chr5:4,451,930–4,866,311, 1 gene, copy number 26 (within-gene range 4–26): AC106799.2.
- chr5:4,640,731–5,140,119, 11 genes, copy number 26: AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2.
- chr5:31,400,497–33,938,918, 50 genes, copy number 7–11: DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160, AC034231.1, TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3.
- chr5:102,371,774–103,031,105, 7 genes, copy number 7: SLCO6A1, AC094108.1, LINC00492, LINC00491, AC099487.1, AC099487.2, PAM.
- chr6:21,354,411–22,654,455, 13 genes, copy number 18–24 (within-gene range 2–24): AL031767.1, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1.
- chr6:30,414,715–31,945,672, 150 genes, copy number 8–181 (within-gene range 2–181) (broad region; genes not listed).
- chr6:63,193,072–63,779,336, 16 genes, copy number 16–134 (within-gene range 2–134): AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr7:157,539,056–158,587,823, 1 gene, copy number 10 (within-gene range 3–23): PTPRN2.
- chr7:157,987,169–157,989,456, 1 gene, copy number 10: AC011899.3.
- chr7:158,532,718–159,233,377, 13 genes, copy number 10–23: MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr10:42,149,310–42,276,842, 4 genes, copy number 9–11: KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2.
- chr11:22,010,402–22,170,001, 2 genes, copy number 7: AC116534.1, AC107882.1.
- chr11:23,154,683–27,363,234, 30 genes, copy number 7–21: LINC02718, AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1, LINC02726, AC100768.1, RNU6-783P, AC099842.1, LINC02686, Y_RNA, LUZP2, AC115990.1, AC087373.1, RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1, ANO3, ANO3-AS1, AC079064.1, MUC15, SLC5A12, FIBIN, BBOX1, BBOX1-AS1, CCDC34.
- chr11:29,335,878–29,989,328, 1 gene, copy number 8 (within-gene range 3–8): LINC02755.
- chr11:29,482,807–33,674,102, 65 genes, copy number 7–16 (within-gene range 3–16) (broad region; genes not listed).
- chr14:18,333,726–18,650,966, 17 genes, copy number 9: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr17:21,075,362–21,193,265, 2 genes, copy number 19: LINC01563, DHRS7B.
- chr17:21,238,870–22,439,033, 29 genes, copy number 9–26: NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4.
- chr17:26,981,694–29,180,398, 131 genes, copy number 13–34 (within-gene range 6–34) (broad region; genes not listed).
- chr17:29,197,071–29,930,276, 32 genes, copy number 15 (within-gene range 2–15): AC005412.1, TWF1P1, CRYBA1, NUFIP2, RPL35AP35, AC068025.2, AC068025.1, RNU4-34P, TAOK1, MIR4523, RNU6-711P, RNU6-1034P, ABHD15, ABHD15-AS1, TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4, CORO6, AC104564.2, SSH2, AC104564.1, RNU6-920P, AC104564.5, RPL21P123, AC023389.1, AC023389.2, SNORA70, RPL9P30, AC104982.2, AC104982.1.
- chr17:30,897,336–31,382,116, 18 genes, copy number 8–12 (within-gene range 2–12): TEFM, AC130324.3, ADAP2, AC138207.1, RN7SL138P, AC138207.5, AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1.
- chr17:31,345,519–31,346,190, 1 gene, copy number 8 (within-gene range 2–8): AK4P1.
- chr17:32,265,832–34,174,964, 45 genes, copy number 7–23 (within-gene range 2–23): RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1, MYO1D, AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3, AC025211.1, Y_RNA, AC084809.1, AC084809.2, TMEM98, SPACA3, ASIC2, AC003687.1, AC008133.2, AC008133.1, AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4.
- chr17:34,155,566–34,165,736, 1 gene, copy number 12 (within-gene range 2–12): AC004147.2.
- chr17:34,255,218–35,121,522, 25 genes, copy number 12: CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1, CCT6B, AC022903.2, ZNF830, LIG3, RFFL, AC004223.3, AC004223.4, AC004223.2, AC004223.1, RAD51D, RNU6-840P, Vault.
- chr17:36,544,912–36,685,129, 6 genes, copy number 12: GGNBP2, AC243732.1, DHRS11, MRM1, AC243830.2, AC243830.3.
- chr17:39,603,536–39,997,959, 21 genes, copy number 14–105: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3.
- chr17:40,993,430–41,668,031, 68 genes, copy number 16 (broad region; genes not listed).
- chr21:9,053,122–9,129,752, 4 genes, copy number 25: CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:10,482,738–13,120,807, 11 genes, copy number 7: AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 168. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
